Somatic mutation profile of tumor specimen 0DVNXE from CCDI case PBCMVD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.6 years (2,766 days).
Specimen 0DVNXE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 177b3ae3-aef0-4547-8651-1ca25caf7b6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVNYM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0275d9c-cf1c-4d40-9ae4-a20370da7072

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Intron 4, Silent 4, Nonsense Mutation 2, RNA 1, In Frame Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BPTF | c.3872G>A p.R1291Q | Missense Mutation (SNP) | VAF 37/770 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs768837896, COSV58830713; called by muse, mutect2
- DENND1B | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 371/960 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs779126393; called by muse, mutect2, varscan2
- GJA5 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 77/362 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs781925387; called by muse, mutect2, varscan2
- H2AC8 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 215/535 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.134); catalogued as COSV55127224; called by muse, mutect2, varscan2
- HUWE1 | c.4004C>A p.A1335E | Missense Mutation (SNP) | VAF 198/540 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53350327; called by muse, mutect2, varscan2
- LNX2 | c.1526G>A p.R509Q | Missense Mutation (SNP) | VAF 164/842 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); catalogued as rs746655734, COSV100310622; called by muse, mutect2, varscan2
- PIK3CG | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 120/664 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as rs1158677193, COSV63252415; called by muse, mutect2, varscan2
- SGCD | c.15G>C p.Q5H (on ENST00000435422 / NM_001128209.2; = p.Q6H on NM_000337.5) | Missense Mutation (SNP) | VAF 28/1103 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100550735; called by muse, mutect2
- TCF7L2 | c.1652C>T p.P551L (on ENST00000355995 / NM_001367943.1; = p.P528L on NM_030756.5) | Missense Mutation (SNP) | VAF 115/451 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.129); catalogued as rs780741000, COSV53346374; called by muse, mutect2, varscan2
- TUBGCP3 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 113/656 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs767141672, COSV56184298; called by muse, mutect2, varscan2
- APOA2 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 20/794 reads (3%) | called by muse, mutect2
- CELSR1 | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.081); called by muse, mutect2
- DLGAP4 | c.2761G>T p.E921* (on ENST00000339266 / NM_001365621.1; = p.E918* on NM_014902.6) | Nonsense Mutation (SNP) | VAF 80/340 reads (24%) | called by muse, mutect2, varscan2
- EGLN2 | c.172T>C p.S58P | Missense Mutation (SNP) | VAF 70/337 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- ENPP7 | c.821A>T p.E274V | Missense Mutation (SNP) | VAF 119/614 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- IKBKB | c.1076T>C p.L359P | Missense Mutation (SNP) | VAF 26/838 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); called by muse, mutect2
- KBTBD4 | c.884_889dup p.P295_R296dup | In Frame Ins (INS) | VAF 148/216 reads (69%) | called by mutect2, varscan2
- MRNIP | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 86/555 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- NBPF1 | c.1904G>C p.R635T | Missense Mutation (SNP) | VAF 27/268 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); called by muse, varscan2
- OR4K15 | c.226G>T p.D76Y (on ENST00000305051; = p.D52Y on NM_001005486.1) | Missense Mutation (SNP) | VAF 100/539 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- PCDHB9 | c.1610G>A p.G537D | Missense Mutation (SNP) | VAF 38/524 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- DCC | c.3756G>A p.P1252= | Silent (SNP) | VAF 313/569 reads (55%) | catalogued as rs183742883, COSV71430330; called by muse, mutect2, varscan2
- FASTKD5 | c.616C>T p.L206= | Silent (SNP) | VAF 14/483 reads (3%) | called by muse, mutect2
- GAL3ST3 | c.366G>A p.P122= | Silent (SNP) | VAF 83/216 reads (38%) | catalogued as rs779460367; called by muse, mutect2, varscan2
- PHLDA1 | c.21C>G p.A7= | Silent (SNP) | VAF 62/282 reads (22%) | catalogued as rs957571678, COSV56998085; called by muse, mutect2, varscan2
- ATP13A2 | c.1542+28G>T | Intron (SNP) | VAF 63/404 reads (16%) | called by muse, mutect2, varscan2
- CCT8 | c.-27G>T | 5'UTR (SNP) | VAF 63/217 reads (29%) | catalogued as rs760436782; called by muse, mutect2, varscan2
- LINC02843 | n.114C>T | RNA (SNP) | VAF 41/141 reads (29%) | catalogued as rs760118074; called by muse, mutect2, varscan2
- PELP1 | c.570+20C>T | Intron (SNP) | VAF 95/446 reads (21%) | catalogued as rs1276748900; called by muse, mutect2, varscan2
- SP110 | c.1706+91C>T | Intron (SNP) | VAF 12/28 reads (43%) | catalogued as rs564584507; called by muse, mutect2, varscan2
- ZSCAN32 | c.695-56C>A | Intron (SNP) | VAF 20/380 reads (5%) | called by muse, mutect2
